Somatic mutation profile of cancer-model specimen HCM-CSHL-0666-C24-85P (3D Organoid, passage 4; aliquot HCM-CSHL-0666-C24-85P-01D-A85K-36), derived from the premalignant tumor of HCMI case HCM-CSHL-0666-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ampulla of Vater; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 70.6 years (25,775 days).
Specimen HCM-CSHL-0666-C24-85P: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) debef24f-dc35-4563-9d85-0a13cf3c214e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0666-C24-10A (Blood Derived Normal), aliquot HCM-CSHL-0666-C24-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0915ed2b-397b-4c7d-b080-1c75acb78684

The open-access MAF lists 129 somatic variants for this specimen: 91 protein-altering or splice-affecting, 30 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 30, Nonsense Mutation 7, Intron 2, 5'Flank 2, Frame Shift Del 2, 3'Flank 2, Frame Shift Ins 1, RNA 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 165/392 reads (42%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- F8 | c.5143C>T p.R1715* | Nonsense Mutation (SNP) | VAF 220/442 reads (50%) | catalogued as rs137852439, CM900094, CM920258, COSV64271015; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.2917C>T p.R973W | Missense Mutation (SNP) | VAF 180/365 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1218643327, COSV60787034; called by muse, mutect2, varscan2
- ADAMTS18 | c.2497G>A p.A833T | Missense Mutation (SNP) | VAF 117/242 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.954); catalogued as rs375093710; called by muse, mutect2, varscan2
- APC | c.3631_3632del p.M1211Vfs*5 | Frame Shift Del (DEL) | VAF 150/412 reads (36%) | catalogued as rs1554085190; called by pindel, varscan2
- ATP2B2 | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 31/467 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1423976084, COSV59495710; called by muse, mutect2
- ATP2B3 | c.2506G>A p.V836I | Missense Mutation (SNP) | VAF 231/512 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs1221371446, COSV54841944; called by muse, mutect2, varscan2
- COL4A4 | c.4700C>T p.A1567V | Missense Mutation (SNP) | VAF 212/553 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs779005474, COSV61635483; called by muse, mutect2, varscan2
- CPZ | c.1882G>A p.D628N (on ENST00000360986 / NM_001014447.3; = p.D617N on NM_003652.3) | Missense Mutation (SNP) | VAF 24/529 reads (5%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs751803458, COSV59926477; called by muse, mutect2
- CTNND1 | c.2107C>T p.R703C (on ENST00000399050 / NM_001085458.2; = p.R697C on NM_001331.3) | Missense Mutation (SNP) | VAF 117/248 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377391701; called by muse, mutect2, varscan2
- DENND1A | c.2407G>A p.A803T | Missense Mutation (SNP) | VAF 170/384 reads (44%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs775924786, COSV101012112, COSV65348181, COSV65348851; called by muse, mutect2, varscan2
- DNAJB2 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 146/365 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs749289057; called by muse, mutect2, varscan2
- DNER | c.1100C>G p.A367G | Missense Mutation (SNP) | VAF 28/384 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.185); catalogued as COSV59174461; called by muse, mutect2
- EDN3 | c.664G>A p.A222T (on ENST00000337938 / NM_001302455.2; = p.A208T on NM_207033.3) | Missense Mutation (SNP) | VAF 194/405 reads (48%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs201352056; called by muse, mutect2, varscan2
- FAT4 | c.8224G>A p.V2742I | Missense Mutation (SNP) | VAF 164/317 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0.054); catalogued as COSV58676406; called by muse, mutect2, varscan2
- FES | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 191/373 reads (51%) | SIFT tolerated (0.28); PolyPhen benign (0.326); catalogued as rs145351114; called by muse, mutect2, varscan2
- FLG | c.9931G>C p.D3311H | Missense Mutation (SNP) | VAF 273/566 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100911422; called by muse, mutect2, varscan2
- FSCB | c.1930G>A p.A644T | Missense Mutation (SNP) | VAF 78/457 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.116); catalogued as rs1256631055, COSV61217101; called by muse, mutect2, varscan2
- GPR183 | c.15G>A p.M5I | Missense Mutation (SNP) | VAF 97/221 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.13); catalogued as rs1175864360; called by muse, mutect2, varscan2
- HECW1 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 46/629 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750970386, COSV67825704; called by muse, mutect2
- ITGAE | c.3211G>A p.E1071K | Missense Mutation (SNP) | VAF 106/231 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV99560030; called by muse, mutect2, varscan2
- KCNB2 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 169/382 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as COSV101578769, COSV73052577; called by muse, mutect2, varscan2
- KCNH1 | c.1019G>A p.G340E | Missense Mutation (SNP) | VAF 123/254 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV55087341; called by muse, mutect2, varscan2
- L1CAM | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 276/569 reads (49%) | SIFT tolerated (0.72); PolyPhen benign (0.01); catalogued as rs782570664, COSV62827452; called by muse, mutect2, varscan2
- MAN2A1 | c.3088G>C p.E1030Q | Missense Mutation (SNP) | VAF 241/488 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1246072934, COSV54856879; called by muse, mutect2, varscan2
- MAP1S | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 18/553 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1037732517; called by muse, mutect2
- MDGA2 | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 215/411 reads (52%) | catalogued as rs966820214, COSV62092848; called by muse, mutect2, varscan2
- MEI1 | c.2415C>G p.F805L | Missense Mutation (SNP) | VAF 257/448 reads (57%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV55903097; called by muse, mutect2, varscan2
- MICAL1 | c.3172G>A p.E1058K | Missense Mutation (SNP) | VAF 177/361 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759678163; called by muse, mutect2, varscan2
- MTG2 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 139/276 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754478626; called by muse, mutect2, varscan2
- MTTP | c.1325A>G p.N442S | Missense Mutation (SNP) | VAF 108/239 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as rs368711749; called by muse, mutect2, varscan2
- NEK4 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 181/437 reads (41%) | catalogued as rs772792374; called by muse, mutect2, varscan2
- NELFCD | c.187C>T p.R63W (on ENST00000602795; = p.R45W on NM_198976.4) | Missense Mutation (SNP) | VAF 130/284 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as rs755253005; called by muse, mutect2, varscan2
- OR10AC1 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 261/561 reads (47%) | SIFT deleterious, low confidence (0.01); catalogued as rs1456382183; called by muse, mutect2, varscan2
- OR2A14 | c.20G>A p.W7* | Nonsense Mutation (SNP) | VAF 130/317 reads (41%) | catalogued as rs1240904773; called by muse, mutect2, varscan2
- OR51I2 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 148/314 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs181429737; called by muse, mutect2, varscan2
- PAPSS2 | c.27G>C p.T9= | Splice Region (SNP) | VAF 211/402 reads (52%) | catalogued as rs759955222; called by muse, mutect2, varscan2
- PHLDA1 | c.751T>G p.Y251D | Missense Mutation (SNP) | VAF 209/406 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs747810433, COSV56997397; called by muse, mutect2, varscan2
- PLEC | c.1550G>A p.R517Q (on ENST00000322810 / NM_201380.4; = p.R407Q on NM_000445.5) | Missense Mutation (SNP) | VAF 150/353 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1410648446; called by muse, mutect2, varscan2
- POLR3C | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 126/302 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as rs1364112287; called by muse, mutect2, varscan2
- PTCD1 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 60/386 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs199936067, COSV52862258, COSV99463956; called by muse, mutect2, varscan2
- RXRB | c.700C>G p.R234G | Missense Mutation (SNP) | VAF 20/555 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100807672; called by muse, mutect2
- S100A7 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 105/359 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs143477256; called by muse, mutect2, varscan2
- SHB | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 168/347 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs985158965; called by muse, mutect2, varscan2
- SIX5 | c.2017G>A p.A673T | Missense Mutation (SNP) | VAF 52/458 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765722531, COSV52177806; called by muse, mutect2, varscan2
- SLC6A2 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 228/503 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV54914074; called by muse, mutect2, varscan2
- SOX11 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 153/352 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100431212; called by muse, mutect2, varscan2
- SV2C | c.823C>T p.R275W | Missense Mutation (SNP) | VAF 194/371 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139844012, COSV59214450; called by muse, mutect2, varscan2
- SYT16 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 106/225 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as rs201271787; called by muse, mutect2, varscan2
- TMEM198 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 243/505 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs749142074; called by muse, mutect2, varscan2
- TRIM46 | c.860C>T p.T287M | Missense Mutation (SNP) | VAF 131/258 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.114); catalogued as rs376400786; called by muse, mutect2, varscan2
- TRPV4 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 147/319 reads (46%) | catalogued as rs1237174071; called by muse, mutect2, varscan2
- TTN | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 196/404 reads (49%) | PolyPhen benign (0.177); catalogued as rs200052202, COSV100618606, COSV59983925; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- XIRP1 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 190/358 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781005341, COSV100453757; called by muse, mutect2, varscan2
- ABCA12 | c.5885G>A p.G1962D (on ENST00000272895 / NM_173076.3; = p.G1644D on NM_015657.3) | Missense Mutation (SNP) | VAF 132/314 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- ADAMTS3 | c.2971G>T p.V991F | Missense Mutation (SNP) | VAF 130/271 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ADORA2A | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 291/569 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- AKT3 | c.9T>A p.D3E | Missense Mutation (SNP) | VAF 247/465 reads (53%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGAP29 | c.2438C>G p.S813* | Nonsense Mutation (SNP) | VAF 98/222 reads (44%) | called by muse, mutect2, varscan2
- ATP7A | c.2648A>G p.K883R | Missense Mutation (SNP) | VAF 167/357 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- BMPR1A | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 152/152 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCNB3 | c.232A>C p.K78Q | Missense Mutation (SNP) | VAF 144/314 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- CMYA5 | c.3311C>G p.S1104C | Missense Mutation (SNP) | VAF 172/342 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- DMD | c.1590A>T p.E530D | Missense Mutation (SNP) | VAF 120/269 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DNAH14 | c.5291T>C p.I1764T (on ENST00000445597; = p.I2169T on NM_001367479.1) | Missense Mutation (SNP) | VAF 11/368 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2
- HCK | c.40C>T p.R14* | Nonsense Mutation (SNP) | VAF 18/513 reads (4%) | called by muse, mutect2
- HDAC9 | c.151C>G p.L51V | Missense Mutation (SNP) | VAF 100/339 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HEATR1 | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 132/304 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JARID2 | c.1591G>C p.E531Q | Missense Mutation (SNP) | VAF 263/564 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- KDM2B | c.2663G>A p.R888H | Missense Mutation (SNP) | VAF 294/599 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KLHL4 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 169/330 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- LUC7L2 | c.603T>A p.D201E | Missense Mutation (SNP) | VAF 16/395 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- MYBBP1A | c.3064G>T p.G1022C | Missense Mutation (SNP) | VAF 53/455 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- MYO18A | c.3162G>T p.W1054C | Missense Mutation (SNP) | VAF 170/373 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MZT2B | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 237/507 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NLRP1 | c.1094T>C p.F365S | Missense Mutation (SNP) | VAF 219/462 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OGT | c.1325C>T p.S442L | Missense Mutation (SNP) | VAF 119/245 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- PTBP2 | c.209A>G p.H70R (on ENST00000426398 / NM_001300986.2; = p.H62R on NM_021190.4) | Missense Mutation (SNP) | VAF 162/325 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- RBM15 | c.1374G>C p.W458C | Missense Mutation (SNP) | VAF 16/383 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- SH3D19 | c.871A>T p.T291S | Missense Mutation (SNP) | VAF 145/256 reads (57%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SNRNP200 | c.1632G>A p.M544I | Missense Mutation (SNP) | VAF 20/414 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- SNTG1 | c.771A>C p.Q257H | Missense Mutation (SNP) | VAF 167/373 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SOX9 | c.574del p.A192Pfs*27 | Frame Shift Del (DEL) | VAF 155/521 reads (30%) | called by mutect2, pindel, varscan2
- TMEM267 | c.476A>G p.D159G | Missense Mutation (SNP) | VAF 161/336 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIP12 | c.1389G>T p.Q463H | Missense Mutation (SNP) | VAF 165/365 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- TRMT11 | c.462T>G p.D154E | Missense Mutation (SNP) | VAF 136/316 reads (43%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TXNRD2 | c.555C>G p.I185M | Missense Mutation (SNP) | VAF 144/302 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- VARS1 | c.2131G>A p.A711T | Missense Mutation (SNP) | VAF 217/455 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZBTB2 | c.1435G>C p.D479H | Missense Mutation (SNP) | VAF 164/336 reads (49%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- ZNF724 | c.946G>A p.G316S | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- ZNF835 | c.450C>A p.S150R | Missense Mutation (SNP) | VAF 224/503 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- ACSL1 | c.1515G>A p.E505= | Silent (SNP) | VAF 128/279 reads (46%) | catalogued as rs913749377; called by muse, mutect2, varscan2
- ASAP1 | c.1287G>A p.A429= | Silent (SNP) | VAF 152/375 reads (41%) | catalogued as rs188105999, COSV63051643; called by muse, mutect2, varscan2
- CENPI | c.1437G>A p.A479= | Silent (SNP) | VAF 60/351 reads (17%) | catalogued as rs747196426, COSV99515129; called by muse, mutect2, varscan2
- DNAH3 | c.11412C>T p.N3804= | Silent (SNP) | VAF 194/396 reads (49%) | catalogued as rs776613491, COSV54511411; called by muse, mutect2, varscan2
- EFEMP1 | c.75G>A p.T25= | Silent (SNP) | VAF 123/266 reads (46%) | catalogued as COSV62616885; called by muse, mutect2
- EPHA6 | c.816T>G p.P272= | Silent (SNP) | VAF 174/389 reads (45%) | called by muse, mutect2, varscan2
- F8 | c.2934A>C p.S978= | Silent (SNP) | VAF 171/387 reads (44%) | called by muse, mutect2, varscan2
- FGD1 | c.1956C>T p.L652= | Silent (SNP) | VAF 190/392 reads (48%) | called by muse, mutect2, varscan2
- FIGNL2 | c.1431C>T p.F477= | Silent (SNP) | VAF 125/230 reads (54%) | called by muse, mutect2, varscan2
- GABBR2 | c.435C>T p.S145= | Silent (SNP) | VAF 156/306 reads (51%) | called by muse, mutect2, varscan2
- GAS8 | c.519G>A p.R173= | Silent (SNP) | VAF 18/462 reads (4%) | catalogued as rs1395267020; called by muse, mutect2
- GJD2 | c.303C>T p.S101= | Silent (SNP) | VAF 162/426 reads (38%) | catalogued as rs747638928, COSV51747266; called by muse, mutect2, varscan2
- GNAS | c.927C>T p.F309= | Silent (SNP) | VAF 39/764 reads (5%) | catalogued as rs777431088; called by muse, mutect2
- IGHG3 | c.951G>A p.P317= | Silent (SNP) | VAF 227/490 reads (46%) | catalogued as rs375664186; called by muse, mutect2, varscan2
- JAKMIP3 | c.1455G>A p.P485= | Silent (SNP) | VAF 113/248 reads (46%) | catalogued as rs752161665; called by muse, varscan2
- KCNH3 | c.1926C>T p.G642= | Silent (SNP) | VAF 190/411 reads (46%) | catalogued as rs1223300697; called by muse, mutect2, varscan2
- KLB | c.2628C>T p.V876= | Silent (SNP) | VAF 242/478 reads (51%) | called by muse, mutect2, varscan2
- KLRF2 | c.510G>A p.R170= | Silent (SNP) | VAF 139/346 reads (40%) | called by muse, mutect2
- MZT2B | c.81G>C p.L27= | Silent (SNP) | VAF 238/508 reads (47%) | called by muse, mutect2, varscan2
- NCAM2 | c.726C>A p.I242= | Silent (SNP) | VAF 121/256 reads (47%) | called by muse, mutect2, varscan2
- NFASC | c.3012C>T p.H1004= | Silent (SNP) | VAF 148/312 reads (47%) | catalogued as rs751833388; called by muse, mutect2, varscan2
- NRROS | c.39C>T p.H13= | Silent (SNP) | VAF 133/308 reads (43%) | catalogued as rs189782443; called by muse, mutect2, varscan2
- OBP2B | c.252G>A p.T84= | Silent (SNP) | VAF 153/341 reads (45%) | catalogued as rs201697602; called by muse, mutect2, varscan2
- PAPPA | c.1308C>T p.D436= | Silent (SNP) | VAF 216/609 reads (35%) | catalogued as rs1231575485, COSV60293313; called by muse, mutect2, varscan2
- PCDHB5 | c.1941C>A p.G647= | Silent (SNP) | VAF 333/719 reads (46%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.2805C>A p.G935= | Silent (SNP) | VAF 214/458 reads (47%) | catalogued as rs779642597; called by muse, mutect2, varscan2
- SETD1B | c.2397C>T p.A799= | Silent (SNP) | VAF 298/597 reads (50%) | catalogued as rs941817496, COSV99931034; called by muse, mutect2, varscan2
- SLITRK3 | c.1761T>A p.G587= | Silent (SNP) | VAF 167/330 reads (51%) | catalogued as COSV53850683; called by muse, mutect2, varscan2
- UBTFL1 | c.285C>T p.N95= | Silent (SNP) | VAF 169/355 reads (48%) | catalogued as rs779661592; called by muse, mutect2, varscan2
- WIZ | c.4542C>G p.S1514= (on ENST00000673675 / NM_001371589.1; = p.S419= on NM_021241.3) | Silent (SNP) | VAF 233/522 reads (45%) | called by muse, mutect2, varscan2
- AC244258.1 | n.585T>C | RNA (SNP) | VAF 69/166 reads (42%) | called by muse, mutect2, varscan2
- CPNE5 | chr6:36843017 C>T | 5'Flank (SNP) | VAF 152/307 reads (50%) | called by muse, mutect2, varscan2
- CRMP1 | chr4:5892726 C>T | 5'Flank (SNP) | VAF 144/284 reads (51%) | called by muse, mutect2, varscan2
- DNAJC12 | c.158-4458G>A | Intron (SNP) | VAF 139/282 reads (49%) | called by muse, mutect2, varscan2
- GPRC6A | c.*1A>C | 3'UTR (SNP) | VAF 16/189 reads (8%) | called by muse, mutect2
- IGFN1 | c.1241+1666C>T | Intron (SNP) | VAF 192/424 reads (45%) | catalogued as rs377263806; called by muse, mutect2, varscan2
- SPANXN4 | chrX:143034677 C>A | 3'Flank (SNP) | VAF 117/258 reads (45%) | catalogued as rs1424408220; called by muse, mutect2, varscan2
- SPANXN4 | chrX:143034678 C>A | 3'Flank (SNP) | VAF 117/258 reads (45%) | called by muse, mutect2, varscan2
